Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3600, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3600-01A (Primary Tumor).

Diagnosis/diagnoses:

1. Peritoneal fatty tissue with necrosis of the fatty tissue, which is not very recent.
2. Resected rectosigmoid sample with a moderately differentiated adenocarcinoma of the colorectal type, measuring a max. of 6 cm, with infiltration of the pericolic fatty tissue and with 30 regional lymph node metastases. Tumor-free colon resection margins. The minimum distance of the tumor to the circumferential resection margin is 1 cm. Tumor-free mesenteric resection margin.
3. (Inguinal [*crossed through and replaced by something illegible*]) lymph node metastasis of the carcinoma described.

Stage of tumor: pT3 pN2 (31/45) pMX; G2, L1, V0, RX

Source: NCI Genomic Data Commons file ccc00d7a-c665-4add-8719-6719991422a2 (TCGA-AG-3600.46665EB7-F30C-4BA3-9B43-46E3F080CD39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).